Somatic mutation profile of tumor specimen TCGA-CM-6676-01A (aliquot TCGA-CM-6676-01A-11D-1835-10) from TCGA case TCGA-CM-6676, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 82.7 years (30,223 days).
Specimen TCGA-CM-6676-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 644e6f70-af52-4c2b-993b-472d7ef0a1ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6676-10A (Blood Derived Normal), aliquot TCGA-CM-6676-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ab955e2-940a-485a-b2a4-d9150c02649f

The open-access MAF lists 107 somatic variants for this specimen: 79 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 26, Nonsense Mutation 8, Frame Shift Ins 2, Splice Site 2, Splice Region 2, Frame Shift Del 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 116/295 reads (39%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 17/107 reads (16%) | hotspot (GDC flag); catalogued as CM992136, COSV57321785, COSV57346425; called by muse, mutect2, varscan2
- CYP11A1 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs776056840, CM1210479, COSV99166146; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 40/68 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC097636.1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369325050; called by muse, mutect2, varscan2
- ACTRT2 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs199702037, COSV65759312; called by muse, mutect2, varscan2
- ADCK5 | c.1450A>T p.I484F | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100450681; called by muse, mutect2
- ADD3 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as rs1398020545, COSV53321133; called by muse, mutect2, varscan2
- AMH | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV55554695; called by muse, varscan2
- APBA1 | c.1350C>A p.C450* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV55227429, COSV55230592; called by muse, mutect2, varscan2
- AQP4 | c.615C>A p.I205= | Splice Region (SNP) | VAF 8/43 reads (19%) | catalogued as COSV101270476, COSV101270561; called by muse, mutect2, varscan2
- BACH2 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.078); catalogued as rs374812157, COSV57607740; called by muse, mutect2, varscan2
- CACNA1E | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62393291; called by muse, mutect2, varscan2
- CACNA1H | c.2604C>T p.S868= | Splice Region (SNP) | VAF 8/45 reads (18%) | catalogued as rs562148225, COSV100673405; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNB1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1239612747, COSV60000004; called by muse, mutect2
- CADPS | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs147087123; called by muse, mutect2, varscan2
- CDC40 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100309550, COSV57008939; called by muse, mutect2
- CDRT1 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs573060209; called by muse, mutect2, varscan2
- CFAP54 | c.5599G>A p.V1867M | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.325); catalogued as rs146798544; called by muse, mutect2, varscan2
- CFAP94 | c.568-1G>T p.X190_splice (on ENST00000320267 / NM_001352064.2; = p.X196_splice on NM_018272.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 31/84 reads (37%) | catalogued as COSV57232080; called by muse, mutect2, varscan2
- CHD5 | c.4279C>T p.R1427* | Nonsense Mutation (SNP) | VAF 6/9 reads (67%) | catalogued as rs749319838, COSV52413883; called by muse, mutect2
- CRMP1 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as rs376257908; called by muse, mutect2, varscan2
- DEDD2 | c.743T>A p.V248D | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV60141843; called by muse, mutect2, varscan2
- DHX9 | c.3598G>A p.G1200S | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV62362897; called by muse, mutect2
- DISP3 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748159081, COSV53826680; called by muse, mutect2, varscan2
- DMD | c.8893G>A p.D2965N | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398124077, COSV58905124, COSV58908980; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP6 | c.746C>A p.P249H (on ENST00000377770 / NM_001364500.2; = p.P187H on NM_001936.5) | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100127856; called by muse, mutect2, varscan2
- FAM110B | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64065013; called by muse, mutect2, varscan2
- FAT4 | c.5444G>A p.R1815H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774484692, COSV58675150, COSV58684354; called by muse, mutect2, varscan2
- FOXS1 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99640191; called by mutect2, varscan2
- FXR1 | c.1022A>C p.K341T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV59762795; called by muse, mutect2, varscan2
- GDA | c.738T>G p.D246E | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV52992890; called by muse, mutect2
- GPLD1 | c.980T>A p.V327E | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs770856721, COSV100015556; called by muse, varscan2
- HELZ2 | c.1755G>T p.E585D (on ENST00000467148 / NM_001037335.2; = p.E16D on NM_033405.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV100915689; called by mutect2, varscan2
- HLA-G | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as rs901286567, COSV64405663; called by muse, mutect2, varscan2
- HMGB2 | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV56633502; called by muse, mutect2, varscan2
- HOOK1 | c.1785A>T p.K595N | Missense Mutation (SNP) | VAF 126/312 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV64618773; called by muse, mutect2, varscan2
- HRNR | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs771199419, COSV64257627; called by muse, mutect2, varscan2
- IGKV1D-12 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs535020629; called by muse, mutect2, varscan2
- INTS11 | c.115T>A p.F39I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV59672224; called by muse, mutect2, varscan2
- ISYNA1 | c.975+1G>A p.X325_splice | Splice Site (SNP) | VAF 17/52 reads (33%) | catalogued as COSV54210302; called by muse, mutect2, varscan2
- ITGAL | c.2819C>T p.T940I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV63322092; called by muse, mutect2, varscan2
- ITIH2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.154); catalogued as rs141514196; called by muse, mutect2, varscan2
- KIAA0408 | c.381dup p.S128Ifs*18 | Frame Shift Ins (INS) | VAF 29/139 reads (21%) | catalogued as rs762399944; called by mutect2, varscan2
- KIFBP | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs774462618, COSV100741433, COSV62555705; called by muse, mutect2, varscan2
- KRTAP24-1 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61089413; called by muse, mutect2, varscan2
- LRP10 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs773603782, COSV62078210; called by muse, mutect2, varscan2
- MESD | c.410A>T p.Q137L | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55725110; called by muse, mutect2, varscan2
- MOS | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV61336014; called by muse, mutect2
- MROH5 | c.2590G>A p.D864N | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs768685918; called by muse, mutect2
- MYLK | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100659544; called by muse, mutect2, varscan2
- NACC1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368391948; called by muse, mutect2, varscan2
- PCDHGA4 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as rs780878681, COSV53943206; called by muse, mutect2, varscan2
- PDXK | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.368); catalogued as COSV52362318; called by muse, mutect2, varscan2
- PLA2R1 | c.4119del p.G1374Afs*32 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs746999253; called by mutect2, varscan2
- RBBP8NL | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs200596881, COSV53348543; called by muse, varscan2
- RBM48 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs953175272, COSV56002650; called by muse, mutect2, varscan2
- RECQL5 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs202162742; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV100271835; called by muse, mutect2, varscan2
- RYR3 | c.4057C>T p.H1353Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101214222; called by muse, mutect2, varscan2
- SLC2A7 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as rs774929471, COSV68901706; called by muse, mutect2, varscan2
- SLC6A4 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771843360, COSV55566579; called by muse, mutect2, varscan2
- SLIT1 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as rs1351333649, COSV56582263; called by muse, mutect2
- SPATC1 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs183194010; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2797C>G p.P933A | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs954516995, COSV59130246; called by muse, mutect2, varscan2
- SYDE2 | c.2455C>A p.Q819K | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV52315410, COSV52318123; called by muse, mutect2, varscan2
- TATDN2 | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55051706; called by muse, mutect2, varscan2
- TBC1D10A | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760105041, COSV53164156; called by muse, mutect2, varscan2
- THAP4 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs770030779, COSV58709597; called by muse, mutect2, varscan2
- TLL1 | c.2416G>T p.A806S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.851); catalogued as COSV50277523; called by muse, mutect2, varscan2
- TMEM67 | c.2974A>T p.R992* | Nonsense Mutation (SNP) | VAF 29/505 reads (6%) | catalogued as COSV60041060; called by muse, mutect2
- TRPC6 | c.2053C>T p.L685F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60254350; called by muse, mutect2, varscan2
- UNC5C | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs987321967, COSV71661448; called by muse, mutect2
- UNC79 | c.4939G>A p.E1647K (on ENST00000393151 / NM_001346218.2; = p.E1470K on NM_020818.5) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV56371866; called by muse, mutect2, varscan2
- VN1R2 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs199981144, COSV59037590, COSV59040122; called by muse, mutect2, varscan2
- ZNF20 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV61998666; called by muse, mutect2, varscan2
- ZNF513 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV52007707; called by muse, mutect2, varscan2
- MOK | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.383); called by muse, mutect2
- VCAN | c.7289dup p.E2431Rfs*10 | Frame Shift Ins (INS) | VAF 14/108 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD36 | c.205C>T p.L69= | Silent (SNP) | VAF 28/231 reads (12%) | catalogued as COSV101347533; called by muse, mutect2
- CACNA1H | c.4299C>T p.I1433= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs764853757, COSV61983560; called by muse, mutect2, varscan2
- CDH8 | c.1128G>A p.A376= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs369487557; called by muse, mutect2, varscan2
- CHRM5 | c.714A>G p.K238= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs139675687; called by mutect2, varscan2
- CLEC1B | c.96G>A p.V32= | Silent (SNP) | VAF 12/294 reads (4%) | catalogued as rs1252756204; called by muse, mutect2
- COL6A3 | c.7356C>T p.N2452= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs569662223, COSV55088626; called by muse, mutect2, varscan2
- CYP27B1 | c.1314C>T p.P438= | Silent (SNP) | VAF 53/105 reads (50%) | catalogued as COSV99141645; called by muse, mutect2, varscan2
- FBXL7 | c.798C>T p.P266= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV61645582; called by muse, mutect2, varscan2
- FRYL | c.3985C>A p.R1329= | Silent (SNP) | VAF 57/164 reads (35%) | catalogued as COSV51940262, COSV51946493; called by muse, mutect2, varscan2
- GPR179 | c.615C>T p.D205= | Silent (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- LRATD2 | c.12G>A p.Q4= | Silent (SNP) | VAF 14/222 reads (6%) | catalogued as COSV100513651; called by muse, mutect2
- MAG | c.1368C>T p.S456= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV62699425; called by muse, mutect2, varscan2
- MAGI3 | c.3000G>A p.Q1000= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV56834813; called by mutect2, varscan2
- NLGN4X | c.1434C>T p.S478= | Silent (SNP) | VAF 73/116 reads (63%) | catalogued as rs398124364, COSV52016572, COSV99320047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN1 | c.4422G>A p.E1474= | Silent (SNP) | VAF 50/150 reads (33%) | catalogued as COSV60497951; called by muse, mutect2, varscan2
- RAB6C | c.30G>A p.P10= | Silent (SNP) | VAF 53/219 reads (24%) | catalogued as COSV69339462; called by muse, mutect2, varscan2
- RAX2 | c.492G>A p.A164= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1014225698, COSV100349755; called by muse, varscan2
- RBMXL2 | c.774C>T p.S258= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs201798501, COSV60979246, COSV99080268; called by muse, mutect2, varscan2
- SOX11 | c.93G>A p.P31= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100431377; called by muse, mutect2
- SPAG6 | c.117C>T p.N39= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV57617979; called by muse, mutect2, varscan2
- TAF1L | c.4464C>A p.I1488= | Silent (SNP) | VAF 27/217 reads (12%) | catalogued as rs1216292342, COSV99645332; called by muse, mutect2, varscan2
- TGFBR2 | c.219C>T p.I73= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV55449481; called by muse, mutect2, varscan2
- TIMP3 | c.603G>A p.P201= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1488001077, COSV56663558; called by muse, mutect2, varscan2
- TP53BP2 | c.708G>T p.L236= (on ENST00000343537 / NM_001031685.3; = p.L107= on NM_005426.2) | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV59068315; called by muse, mutect2, varscan2
- TTC29 | c.255C>T p.F85= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1422800958, COSV57274922; called by muse, mutect2, varscan2
- WASF2 | c.273G>A p.L91= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV71005505; called by muse, mutect2, varscan2
- DNAH8 | chr6:38723102 C>T | 5'Flank (SNP) | VAF 19/62 reads (31%) | catalogued as COSV59427200; called by muse, mutect2, varscan2
- HMGB1P1 | n.197C>T | RNA (SNP) | VAF 22/276 reads (8%) | catalogued as rs759047604; called by muse, mutect2
